CPTAC case C3L-01668 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b75eef43-e157-428d-8cef-198f5593165b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1980; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 37.3 years (13,619 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 2,002 days (5.5 years); Progression or recurrence: no; Days to last follow up: 2,002 days (5.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Margin status: Indeterminate.

Follow-up (6 entries)
- Days to follow up: 377 days (1.0 years); Disease response: Complete Response.
- Days to follow up: 377 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 1,199 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,563 days (4.3 years); Disease response: Tumor Free.
- Days to follow up: 1,910 days (5.2 years); Disease response: Tumor Free.
- Days to follow up: 2,002 days (5.5 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 116.57 kg; Height: 162.56 cm; BMI: 44.11.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01668-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 197 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01668-21: Section location: Anterios and Posterior Endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-01668-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
